Gene-level copy-number profile of tumor specimen TCGA-29-1777-01A from TCGA case TCGA-29-1777, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 47.5 years (17,356 days).
Specimen TCGA-29-1777-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7a40175f-a23d-4540-a3b2-5a147430ffc7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1777-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf2fa733-5260-4e42-9f36-9dcd52e47005

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 21,281; copy number 2: 32,315; copy number 3: 4,766; copy number 4: 505; copy number 5: 921.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1777-01A-01D-0577-01): tumor purity 0.81, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–116,582,830, 2 genes: LINC00903, RN7SL582P.
- chr4:168,755,816–168,844,735, 3 genes: RPL9P16, AC080188.1, AC080188.2.
- chr4:168,885,355–168,885,461, 1 gene: RNU6-853P.
- chr5:144,522,140–144,535,670, 2 genes: AC008716.1, RN7SKP246.
- chr11:5,761,153–5,801,297, 4 genes: OR56B2P, OR52N5, OR52N1, OR52N3P.
- chr13:48,232,612–48,303,661, 2 genes (within-gene range 0–1): ITM2B, RB1-DT.
- chr13:48,316,863–48,341,330, 3 genes: PPP1R26P1, PCNPP5, AL392048.1.
- chr15:59,049,399–59,050,385, 1 gene: AC092757.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 921 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,008,689–198,222,513, 600 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:58,198–16,033,356, 280 genes, copy number 5 (broad region; genes not listed).
- chr6:18,223,860–18,674,001, 9 genes, copy number 5: DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1.
- chr7:130,506,238–130,668,748, 1 gene, copy number 5 (within-gene range 3–5): COPG2.
- chr7:130,538,954–131,496,632, 22 genes, copy number 5 (within-gene range 3–5): AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS.
- chr7:139,777,051–140,293,339, 9 genes, copy number 5 (within-gene range 3–5): TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6.

Autosomal genes at a single copy (total copy number 1): 19,235. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
